Somatic mutation profile of tumor specimen HCM-CSHL-0371-C25-01A (aliquot HCM-CSHL-0371-C25-01A-11D-A78L-36) from HCMI case HCM-CSHL-0371-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 75.0 years (27,380 days).
Specimen HCM-CSHL-0371-C25-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e9c48f3c-22fa-4a94-b114-cdac3e4f60b6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0371-C25-10A (Blood Derived Normal), aliquot HCM-CSHL-0371-C25-10A-01D-A78L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/05c89973-6fbc-42ec-aca6-e106a3bdf2c5

The open-access MAF lists 126 somatic variants for this specimen: 80 protein-altering or splice-affecting, 30 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 66, Silent 30, Nonsense Mutation 6, RNA 5, 5'UTR 4, Intron 4, In Frame Del 3, Frame Shift Ins 3, 3'UTR 2, 3'Flank 1, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 75/256 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1245_1248del p.D415Efs*20 | Frame Shift Del (DEL) | VAF 43/170 reads (25%) | catalogued as rs80338965; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ACE2 | c.2147G>A p.R716H | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.277); catalogued as rs200540199, COSV53025304; called by muse, mutect2, varscan2
- AGR3 | c.379A>G p.T127A | Missense Mutation (SNP) | VAF 47/125 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as rs1432614011; called by muse, mutect2, varscan2
- AGRN | c.4202G>T p.R1401L | Missense Mutation (SNP) | VAF 45/172 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.897); catalogued as rs777248655; called by muse, mutect2, varscan2
- ALB | c.1195G>A p.D399N | Missense Mutation (SNP) | VAF 29/136 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as rs77514449, CM870085, CM984717; ClinVar: other; called by muse, mutect2, varscan2
- ATP5PB | c.623G>T p.R208L | Missense Mutation (SNP) | VAF 31/137 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.135); catalogued as COSV63853787; called by muse, mutect2, varscan2
- ATP7B | c.3643G>T p.D1215Y | Missense Mutation (SNP) | VAF 193/579 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as CM016059, COSV54435316; called by muse, mutect2, varscan2
- BAIAP3 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 30/169 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.349); catalogued as rs369126457; called by muse, mutect2, varscan2
- BCL6B | c.20C>A p.P7Q | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as rs762380355; called by muse, mutect2, varscan2
- CASR | c.2991C>A p.N997K (on ENST00000490131; = p.N1074K on NM_000388.4) | Missense Mutation (SNP) | VAF 43/209 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs1182793884, COSV56138916; called by muse, mutect2, varscan2
- CRB1 | c.2219C>A p.S740Y | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM120681; called by muse, mutect2, varscan2
- DCHS1 | c.1285C>T p.R429W | Missense Mutation (SNP) | VAF 52/250 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.713); catalogued as rs369236555; called by muse, mutect2, varscan2
- DNAJB4 | c.116_118del p.P39del | In Frame Del (DEL) | VAF 50/226 reads (22%) | catalogued as rs759396618; called by pindel, varscan2
- FEZF2 | c.1067C>A p.A356E | Missense Mutation (SNP) | VAF 51/250 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51863083; called by muse, mutect2, varscan2
- GEMIN5 | c.2344G>A p.G782R | Missense Mutation (SNP) | VAF 64/376 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.4); catalogued as COSV53561105; called by muse, mutect2, varscan2
- JRK | c.283G>T p.E95* | Nonsense Mutation (SNP) | VAF 33/143 reads (23%) | catalogued as COSV70630291; called by muse, mutect2, varscan2
- LCE3A | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 123/519 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); catalogued as COSV100175092, COSV59551214; called by muse, mutect2, varscan2
- MAU2 | c.979G>T p.D327Y | Missense Mutation (SNP) | VAF 47/198 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV53236669; called by muse, mutect2, varscan2
- MTA1 | c.1954G>A p.D652N | Missense Mutation (SNP) | VAF 55/222 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as COSV100231719; called by muse, mutect2, varscan2
- NBPF20 | c.16753G>T p.D5585Y (on ENST00000369373; = p.D5146Y on NM_001278267.1) | Missense Mutation (SNP) | VAF 130/571 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs1243615397; called by muse, mutect2, varscan2
- NEIL3 | c.447G>A p.M149I | Missense Mutation (SNP) | VAF 37/142 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs1363392369; called by muse, mutect2, varscan2
- P3H4 | c.580G>T p.E194* | Nonsense Mutation (SNP) | VAF 54/188 reads (29%) | catalogued as rs374170886; called by muse, mutect2, varscan2
- PAGE5 | c.19G>A p.G7S | Missense Mutation (SNP) | VAF 65/202 reads (32%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs761008332; called by muse, mutect2, varscan2
- PCDHAC2 | c.485C>T p.A162V | Missense Mutation (SNP) | VAF 41/237 reads (17%) | SIFT tolerated (0.84); PolyPhen benign (0.005); catalogued as COSV99150718; called by muse, mutect2, varscan2
- PCLO | c.12193G>T p.A4065S | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT tolerated (0.62); PolyPhen benign (0.053); catalogued as COSV61613061; called by muse, mutect2, varscan2
- RYR1 | c.3994G>A p.E1332K | Missense Mutation (SNP) | VAF 251/546 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as rs896157692, COSV62100300; called by muse, mutect2, varscan2
- SCN7A | c.1495C>A p.H499N | Missense Mutation (SNP) | VAF 33/171 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.039); catalogued as COSV69271739; called by muse, mutect2, varscan2
- SLC26A3 | c.542C>T p.S181L | Missense Mutation (SNP) | VAF 76/452 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.106); catalogued as COSV60643165; called by muse, mutect2, varscan2
- SLC43A3 | c.761C>T p.A254V | Missense Mutation (SNP) | VAF 44/184 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as rs762938193; called by muse, mutect2, varscan2
- SPART | c.1399G>T p.V467L | Missense Mutation (SNP) | VAF 71/317 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.019); catalogued as COSV62086217; called by muse, mutect2, varscan2
- TMEM132C | c.527G>A p.R176Q | Missense Mutation (SNP) | VAF 81/299 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.043); catalogued as rs761061229, COSV70656371; called by muse, mutect2, varscan2
- TMEM132C | c.1097G>T p.R366L | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as rs201621009; called by muse, mutect2, varscan2
- UTS2R | c.709G>A p.A237T | Missense Mutation (SNP) | VAF 72/278 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.07); catalogued as rs1304082639; called by muse, mutect2, varscan2
- VCPIP1 | c.2017G>T p.A673S | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.042); catalogued as COSV60050535; called by muse, mutect2, varscan2
- VHL | c.323G>T p.R108L | Missense Mutation (SNP) | VAF 90/405 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as rs367594943, CD056864; called by muse, mutect2, varscan2
- VN1R2 | c.617C>A p.P206Q | Missense Mutation (SNP) | VAF 100/249 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.804); catalogued as COSV59037539, COSV59037950; called by muse, mutect2, varscan2
- WNK2 | c.5357C>T p.S1786L (on ENST00000297954 / NM_001282394.1; = p.S1749L on NM_006648.3) | Missense Mutation (SNP) | VAF 31/165 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs147131740; called by muse, mutect2, varscan2
- ZFP69 | c.560C>T p.T187M | Missense Mutation (SNP) | VAF 57/295 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.763); catalogued as rs146417933; called by muse, mutect2, varscan2
- ZNF208 | c.3008G>A p.C1003Y | Missense Mutation (SNP) | VAF 70/384 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs896836007; called by muse, mutect2, varscan2
- ADGRA3 | c.3869G>T p.G1290V | Missense Mutation (SNP) | VAF 41/221 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.331); called by muse, mutect2, varscan2
- ADGRA3 | c.3868G>T p.G1290* | Nonsense Mutation (SNP) | VAF 41/221 reads (19%) | called by muse, mutect2, varscan2
- ALCAM | c.1234G>A p.V412I | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- AQR | c.1238G>T p.R413L | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- COLEC11 | c.442G>T p.E148* | Nonsense Mutation (SNP) | VAF 112/436 reads (26%) | called by muse, mutect2, varscan2
- CTTNBP2 | c.67G>T p.A23S | Missense Mutation (SNP) | VAF 50/251 reads (20%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0); called by muse, mutect2, varscan2
- EPHA2 | c.50C>A p.A17E | Missense Mutation (SNP) | VAF 38/170 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- FADS1 | c.833C>G p.A278G | Missense Mutation (SNP) | VAF 66/233 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.457); called by muse, mutect2, varscan2
- FAM170B | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 73/291 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FMN2 | c.715G>A p.V239I | Missense Mutation (SNP) | VAF 52/239 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GOT1L1 | c.40C>A p.H14N | Missense Mutation (SNP) | VAF 46/150 reads (31%) | SIFT tolerated (0.48); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- JMJD6 | c.129G>T p.A43= | Splice Region (SNP) | VAF 43/165 reads (26%) | called by muse, mutect2, varscan2
- LANCL2 | c.448G>T p.G150W | Missense Mutation (SNP) | VAF 99/561 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LANCL2 | c.449G>T p.G150V | Missense Mutation (SNP) | VAF 98/561 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LIN37 | c.271C>T p.R91* | Nonsense Mutation (SNP) | VAF 20/101 reads (20%) | called by muse, mutect2, varscan2
- LMOD2 | c.816C>A p.N272K | Missense Mutation (SNP) | VAF 73/188 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- MACF1 | c.13316T>G p.M4439R (on ENST00000372915; = p.M2372R on NM_012090.5) | Missense Mutation (SNP) | VAF 16/50 reads (32%) | called by muse, varscan2
- MAP4 | c.3119G>T p.G1040V | Missense Mutation (SNP) | VAF 48/256 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MAP4 | c.3118G>T p.G1040W | Missense Mutation (SNP) | VAF 48/256 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAPK15 | c.749G>T p.R250L | Missense Mutation (SNP) | VAF 54/208 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.308); called by muse, mutect2, varscan2
- MAZ | c.401dup p.P135Sfs*196 | Frame Shift Ins (INS) | VAF 18/36 reads (50%) | called by mutect2, varscan2
- MTBP | c.262G>C p.G88R | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MTBP | c.263G>T p.G88V | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MTCL1 | c.1704_1707dup p.R570Afs*58 (on ENST00000306329 / NM_001378206.1; = p.R210Afs*58 on NM_015210.4) | Frame Shift Ins (INS) | VAF 24/88 reads (27%) | called by mutect2, pindel, varscan2
- MUC7 | c.319G>T p.A107S | Missense Mutation (SNP) | VAF 51/281 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.015); called by muse, varscan2
- MYCT1 | c.437G>T p.R146L | Missense Mutation (SNP) | VAF 54/165 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NCKAP1 | c.155dup p.N52Kfs*53 | Frame Shift Ins (INS) | VAF 37/195 reads (19%) | called by mutect2, pindel, varscan2
- NPTX2 | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 29/251 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PFKM | c.2333C>A p.A778D | Missense Mutation (SNP) | VAF 57/255 reads (22%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PSMG1 | c.677G>T p.W226L | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.978); called by muse, mutect2
- PUM2 | c.1862C>T p.P621L | Missense Mutation (SNP) | VAF 63/313 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SERPINI1 | c.240C>A p.S80R | Missense Mutation (SNP) | VAF 25/147 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TNFRSF8 | c.1083T>A p.S361R | Missense Mutation (SNP) | VAF 55/210 reads (26%) | SIFT tolerated (0.6); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- TP53 | c.463_471del p.T155_V157del | In Frame Del (DEL) | VAF 49/172 reads (28%) | called by mutect2, pindel, varscan2
- UPF3A | c.1104G>T p.R368S | Missense Mutation (SNP) | VAF 73/229 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- USP20 | c.1495_1524del p.K499_A508del | In Frame Del (DEL) | VAF 26/286 reads (9%) | called by mutect2, pindel
- VGLL3 | c.308A>C p.D103A | Missense Mutation (SNP) | VAF 63/279 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WDR72 | c.19G>T p.A7S | Missense Mutation (SNP) | VAF 59/328 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- ZCWPW1 | c.436C>A p.P146T | Missense Mutation (SNP) | VAF 79/230 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- ZNF680 | c.73G>T p.E25* | Nonsense Mutation (SNP) | VAF 33/309 reads (11%) | called by muse, mutect2, varscan2
- ATP7B | c.3642G>A p.V1214= | Silent (SNP) | VAF 190/574 reads (33%) | catalogued as rs1408214363; called by muse, mutect2, varscan2
- COX5B | c.42G>T p.A14= | Silent (SNP) | VAF 48/158 reads (30%) | called by muse, mutect2, varscan2
- CYP4A22 | c.312T>C p.Y104= | Silent (SNP) | VAF 32/163 reads (20%) | called by muse, mutect2, varscan2
- DPP4 | c.663T>A p.T221= | Silent (SNP) | VAF 37/200 reads (19%) | catalogued as rs200855838, COSV100858977, COSV62108592; called by muse, mutect2, varscan2
- EVPL | c.2085G>A p.A695= | Silent (SNP) | VAF 40/161 reads (25%) | catalogued as rs761006934, COSV56908653; called by muse, mutect2, varscan2
- GLI3 | c.1920G>A p.K640= | Silent (SNP) | VAF 63/489 reads (13%) | called by muse, mutect2, varscan2
- GOLGA6L7 | c.447C>T p.H149= | Silent (SNP) | VAF 95/385 reads (25%) | catalogued as rs577453827, COSV73845695; called by muse, mutect2, varscan2
- GOT1L1 | c.39C>A p.A13= | Silent (SNP) | VAF 47/154 reads (31%) | called by muse, mutect2, varscan2
- HMGXB3 | c.3519T>C p.F1173= (on ENST00000613459; = p.F927= on NM_014983.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 76/465 reads (16%) | catalogued as rs990208152; called by muse, mutect2, varscan2
- IL18RAP | c.1563G>A p.E521= | Silent (SNP) | VAF 19/82 reads (23%) | catalogued as rs540633615; called by muse, mutect2, varscan2
- INSYN1 | c.273C>A p.G91= | Silent (SNP) | VAF 57/278 reads (21%) | catalogued as COSV65837985; called by muse, mutect2, varscan2
- KRTAP5-2 | c.36C>T p.S12= | Silent (SNP) | VAF 31/182 reads (17%) | catalogued as rs368764083; called by muse, mutect2, varscan2
- LRRC4B | c.288C>T p.N96= | Silent (SNP) | VAF 61/348 reads (18%) | catalogued as rs199856706; called by muse, mutect2, varscan2
- MARCHF4 | c.1224G>A p.T408= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as rs201288119, COSV56104315; called by muse, mutect2, varscan2
- MAU2 | c.978G>T p.L326= | Silent (SNP) | VAF 45/194 reads (23%) | called by muse, mutect2, varscan2
- MUC7 | c.318G>T p.V106= | Silent (SNP) | VAF 50/278 reads (18%) | called by muse, varscan2
- NACA | c.63T>A p.A21= | Silent (SNP) | VAF 76/266 reads (29%) | called by muse, mutect2, varscan2
- NLRP6 | c.2367G>A p.T789= | Silent (SNP) | VAF 18/88 reads (20%) | catalogued as rs138103882; called by muse, mutect2, varscan2
- OR8H3 | c.324T>A p.G108= | Silent (SNP) | VAF 50/238 reads (21%) | catalogued as COSV57907868; called by muse, mutect2, varscan2
- SCN7A | c.1494C>A p.V498= | Silent (SNP) | VAF 32/171 reads (19%) | called by muse, mutect2, varscan2
- SIPA1L2 | c.924G>T p.T308= | Silent (SNP) | VAF 41/189 reads (22%) | called by muse, mutect2, varscan2
- SLC46A1 | c.732G>A p.T244= | Silent (SNP) | VAF 52/229 reads (23%) | catalogued as rs782240737; called by muse, mutect2, varscan2
- TFG | c.1146G>A p.A382= | Silent (SNP) | VAF 34/109 reads (31%) | catalogued as rs761808737; ClinVar: likely benign; called by muse, mutect2, varscan2
- TPRX1 | c.207G>A p.T69= | Silent (SNP) | VAF 36/127 reads (28%) | catalogued as rs760804536; called by muse, mutect2, varscan2
- TRPM8 | c.1632C>T p.D544= | Silent (SNP) | VAF 44/154 reads (29%) | catalogued as rs142882642; called by muse, varscan2
- TSEN54 | c.933C>T p.R311= | Silent (SNP) | VAF 65/257 reads (25%) | called by muse, mutect2, varscan2
- USP34 | c.279G>T p.T93= | Silent (SNP) | VAF 41/246 reads (17%) | called by muse, varscan2
- XAB2 | c.231G>T p.A77= | Silent (SNP) | VAF 26/139 reads (19%) | catalogued as COSV60697387; called by muse, mutect2, varscan2
- ZHX2 | c.1101G>T p.P367= | Silent (SNP) | VAF 59/231 reads (26%) | called by muse, mutect2, varscan2
- ZNF680 | c.72G>T p.L24= | Silent (SNP) | VAF 33/312 reads (11%) | called by muse, mutect2, varscan2
- AC018638.4 | n.612C>T | RNA (SNP) | VAF 81/208 reads (39%) | catalogued as rs1329890853; called by muse, mutect2, varscan2
- AC114482.1 | chr1:84631679 A>G | 3'Flank (SNP) | VAF 43/247 reads (17%) | catalogued as rs551613791; called by muse, varscan2
- BLACE | n.1549G>T | RNA (SNP) | VAF 69/362 reads (19%) | called by muse, mutect2, varscan2
- CALD1 | c.2295+2199_2295+2201dup | Intron (INS) | VAF 84/224 reads (38%) | called by mutect2, pindel, varscan2
- COL18A1-AS1 | n.1439C>A | RNA (SNP) | VAF 34/170 reads (20%) | called by muse, mutect2, varscan2
- GPT | c.-46T>G | 5'UTR (SNP) | VAF 64/234 reads (27%) | called by muse, mutect2, varscan2
- MYO1E | c.-31_-30del | 5'UTR (DEL) | VAF 44/219 reads (20%) | called by mutect2, pindel, varscan2
- PTK2 | c.2946+2144A>G | Intron (SNP) | VAF 5/24 reads (21%) | called by muse, mutect2, varscan2
- RAD51D | c.*629G>T | 3'UTR (SNP) | VAF 69/327 reads (21%) | called by muse, mutect2, varscan2
- SLC22A20P | n.1227C>A | RNA (SNP) | VAF 46/201 reads (23%) | catalogued as rs764483676; called by muse, mutect2, varscan2
- SLC35F1 | c.-4C>T | 5'UTR (SNP) | VAF 40/223 reads (18%) | called by muse, mutect2, varscan2
- SMARCA4 | c.3168+14G>T | Intron (SNP) | VAF 88/353 reads (25%) | called by muse, mutect2, varscan2
- SSPOP | n.13614G>T | RNA (SNP) | VAF 24/153 reads (16%) | catalogued as rs375458504; called by muse, mutect2, varscan2
- TRMU | c.1019-49G>T | Intron (SNP) | VAF 69/215 reads (32%) | catalogued as rs371352968; called by muse, mutect2, varscan2
- UBXN2B | c.-22G>T | 5'UTR (SNP) | VAF 6/13 reads (46%) | catalogued as rs1444858257; called by muse, mutect2, varscan2
- UNC13D | c.*442C>T | 3'UTR (SNP) | VAF 16/62 reads (26%) | called by muse, mutect2
